Somatic mutation profile of tumor specimen cfd76f9a-ce60-4ec7-8e6b-a8fc31 (aliquot cfd76f9a-ce60-4ec7-8e6b-a8fc31_D6) from CPTAC case 17OV011, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary.
Specimen cfd76f9a-ce60-4ec7-8e6b-a8fc31: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23745562-4b23-47c6-95da-8a9383983a61.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen d606e01a-a0b6-4126-ade0-dd9fba (Blood Derived Normal), aliquot d606e01a-a0b6-4126-ade0-dd9fba_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ebdefdd3-d3b0-4640-9406-fa231a5ef947

The open-access MAF lists 87 somatic variants for this specimen: 59 protein-altering or splice-affecting, 18 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 18, Intron 4, Splice Site 3, RNA 2, Splice Region 2, 3'UTR 2, Nonsense Mutation 1, Frame Shift Ins 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.672+1G>A p.X224_splice | Splice Site (SNP) | VAF 449/722 reads (62%) | hotspot (GDC flag); catalogued as rs863224499, CS071266, CS123101, COSV52670407, COSV52712339, COSV52751788; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- BRD4 | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as rs1348283029; called by muse, mutect2
- C1QB | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 39/275 reads (14%) | catalogued as rs751172449, CM880014; called by muse, mutect2, varscan2
- CARMIL3 | c.4001G>A p.R1334Q | Missense Mutation (SNP) | VAF 38/353 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); catalogued as rs576168984, COSV53746036; called by muse, mutect2, varscan2
- CCM2 | c.179G>A p.S60N | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs760398669; called by muse, mutect2
- CNGA1 | c.1096G>A p.V366M | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); catalogued as rs758625358; called by muse, mutect2, varscan2
- EIF4A1 | c.1076+7G>A | Splice Region (SNP) | VAF 31/335 reads (9%) | catalogued as rs748279799; called by muse, mutect2
- ERICH1 | c.986A>G p.D329G | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as rs1200351000; called by muse, mutect2, varscan2
- GLB1L2 | c.284+1G>A p.X95_splice | Splice Site (SNP) | VAF 15/97 reads (15%) | catalogued as rs750611640, COSV60278311; called by muse, mutect2, varscan2
- GOLGA8F | c.724C>T p.P242S (on ENST00000526619; = p.P448S on NM_001350920.2) | Missense Mutation (SNP) | VAF 28/455 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.306); catalogued as rs1360931024; called by muse, mutect2
- H2AC4 | c.13G>A p.G5S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.796); catalogued as rs749277738; called by muse, mutect2, varscan2
- HSPG2 | c.7978A>G p.I2660V | Missense Mutation (SNP) | VAF 120/862 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs766810080; called by muse, mutect2, varscan2
- HUWE1 | c.4231C>T p.R1411W | Missense Mutation (SNP) | VAF 74/474 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs1325872946; called by muse, mutect2, varscan2
- IFITM3 | c.209C>A p.P70H | Missense Mutation (SNP) | VAF 33/317 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs775514515; called by muse, mutect2, varscan2
- KNDC1 | c.416A>T p.E139V | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV58836019; called by muse, mutect2
- MAS1 | c.953C>T p.T318M | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.154); catalogued as rs148082809, COSV53121769; called by muse, mutect2, varscan2
- MED24 | c.2395C>T p.H799Y | Missense Mutation (SNP) | VAF 29/217 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as rs1385124494; called by muse, mutect2, varscan2
- MYOM2 | c.3649G>C p.G1217R | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV50772504; called by muse, mutect2, varscan2
- NDUFV1 | c.674T>C p.L225P | Missense Mutation (SNP) | VAF 55/409 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1048338020; called by muse, mutect2, varscan2
- NLRP4 | c.2681G>A p.R894H | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs772339690, COSV100016655; called by muse, mutect2, varscan2
- OR10Q1 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 68/556 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs1369921729, COSV57469928; called by muse, mutect2, varscan2
- PIK3R2 | c.442C>G p.P148A | Missense Mutation (SNP) | VAF 106/498 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV55851111; called by muse, mutect2, varscan2
- SCN9A | c.1325C>T p.A442V | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs773066209, COSV57602252; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC22A15 | c.1499C>T p.S500L | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.548); catalogued as rs529738399, COSV65679625, COSV65680059; called by muse, mutect2, varscan2
- SLIT1 | c.3587C>T p.T1196M | Missense Mutation (SNP) | VAF 29/251 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1490189979, COSV56589657; called by muse, mutect2, varscan2
- SRGAP2 | c.865C>T p.R289W (on ENST00000624873 / NM_001170637.4; = p.R290W on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/446 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1553355465, COSV99832751; called by muse, mutect2, varscan2
- TCF21 | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 46/320 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1344260202, COSV52818773; called by mutect2, varscan2
- TNRC6C | c.3034G>A p.V1012M | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs752221819; called by muse, mutect2, varscan2
- UBQLN2 | c.1239C>G p.S413R | Missense Mutation (SNP) | VAF 63/521 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.191); catalogued as rs748752063; called by muse, mutect2, varscan2
- ZNF219 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs957075642; called by muse, mutect2
- ACOT4 | c.770C>A p.S257Y | Missense Mutation (SNP) | VAF 28/289 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGAP6 | c.1681A>C p.N561H | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BMPR2 | c.1028dup p.N343Kfs*2 | Frame Shift Ins (INS) | VAF 72/194 reads (37%) | called by mutect2, pindel, varscan2
- CDK5RAP2 | c.3205C>G p.P1069A | Missense Mutation (SNP) | VAF 34/281 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CRHBP | c.174G>C p.L58= | Splice Region (SNP) | VAF 22/125 reads (18%) | called by muse, mutect2
- FRMD1 | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 36/272 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FTL | c.397C>G p.H133D | Missense Mutation (SNP) | VAF 27/262 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2
- HCFC2 | c.1164G>T p.L388F | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIAA0408 | c.941C>A p.P314H | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- KIF20B | c.4048A>G p.N1350D (on ENST00000371728 / NM_001284259.2; = p.N1310D on NM_016195.4) | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2
- KIRREL2 | c.1730C>G p.P577R | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.997); called by muse, mutect2
- KMT2D | c.7698T>G p.F2566L | Missense Mutation (SNP) | VAF 114/364 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0); called by mutect2, varscan2
- MTMR14 | c.494-1G>C p.X165_splice | Splice Site (SNP) | VAF 17/161 reads (11%) | called by muse, mutect2
- MUC4 | c.9671C>T p.S3224L | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- OR2F1 | c.187C>T p.L63F | Missense Mutation (SNP) | VAF 31/502 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDH9 | c.1314A>C p.K438N | Missense Mutation (SNP) | VAF 87/178 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PCSK9 | c.82G>T p.A28S | Missense Mutation (SNP) | VAF 70/443 reads (16%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); called by muse, varscan2
- PELI2 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 22/215 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PLXNB3 | c.769G>T p.A257S | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RAPGEF3 | c.2585C>G p.P862R (on ENST00000389212; = p.P820R on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 124/547 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- SCN2A | c.1210T>A p.F404I | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SOD3 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TOX3 | c.1139C>A p.P380H | Missense Mutation (SNP) | VAF 52/632 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); called by muse, mutect2
- TTN | c.27630G>T p.W9210C (on ENST00000591111; = p.W8283C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/686 reads (4%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- VWA5B2 | c.3671G>C p.R1224P | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- WDR74 | c.570G>C p.Q190H | Missense Mutation (SNP) | VAF 48/361 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF236 | c.3077G>A p.S1026N | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF407 | c.757T>A p.C253S | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- ZNF525 | c.365G>C p.S122T | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- AC138647.1 | c.69C>T p.G23= | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as rs1055404968; called by muse, mutect2, varscan2
- ADAM19 | c.849C>T p.L283= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as rs375976246; called by muse, mutect2, varscan2
- ARHGAP4 | c.2217C>T p.P739= | Silent (SNP) | VAF 152/563 reads (27%) | catalogued as rs549301187; called by muse, mutect2, varscan2
- CATSPER2 | c.498A>G p.L166= | Silent (SNP) | VAF 21/151 reads (14%) | called by muse, mutect2, varscan2
- CD40LG | c.594C>T p.P198= | Silent (SNP) | VAF 40/257 reads (16%) | catalogued as rs370353192, CD050483, COSV101033448, COSV101033572, COSV65699141; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EXPH5 | c.4365A>G p.P1455= | Silent (SNP) | VAF 12/88 reads (14%) | called by muse, mutect2, varscan2
- GJA3 | c.138C>A p.G46= | Silent (SNP) | VAF 10/132 reads (8%) | catalogued as rs1566515379, COSV53834062; called by muse, mutect2
- GYS2 | c.1956C>T p.S652= | Silent (SNP) | VAF 23/332 reads (7%) | called by muse, mutect2
- HS3ST3A1 | c.624C>T p.D208= | Silent (SNP) | VAF 21/214 reads (10%) | catalogued as rs369654526; called by muse, mutect2
- KCNMB4 | c.288T>C p.S96= | Silent (SNP) | VAF 16/300 reads (5%) | catalogued as rs776418718; called by muse, mutect2
- MECR | c.876C>G p.P292= | Silent (SNP) | VAF 25/140 reads (18%) | catalogued as COSV55284163, COSV55286889; called by muse, mutect2, varscan2
- OBSL1 | c.2886C>T p.L962= | Silent (SNP) | VAF 32/348 reads (9%) | catalogued as rs757808976; called by muse, mutect2
- PTPN13 | c.2661G>A p.S887= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs764785783; called by muse, mutect2, varscan2
- RBP3 | c.3375C>T p.H1125= | Silent (SNP) | VAF 94/583 reads (16%) | catalogued as rs782017420; called by muse, mutect2, varscan2
- SLC34A1 | c.294C>T p.G98= | Silent (SNP) | VAF 128/729 reads (18%) | catalogued as rs767269039; called by muse, mutect2, varscan2
- TENM3 | c.7710G>T p.A2570= | Silent (SNP) | VAF 35/194 reads (18%) | catalogued as COSV101305174; called by muse, mutect2, varscan2
- YWHAE | c.684G>C p.L228= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV51985493; called by muse, mutect2, varscan2
- ZNF778 | c.1206C>T p.F402= | Silent (SNP) | VAF 26/259 reads (10%) | called by muse, mutect2, varscan2
- C14orf177 | n.525C>A | RNA (SNP) | VAF 46/426 reads (11%) | catalogued as COSV100362736; called by muse, mutect2, varscan2
- C5orf67 | n.284G>T | RNA (SNP) | VAF 10/81 reads (12%) | catalogued as rs745900291; called by muse, mutect2, varscan2
- C7orf57 | c.-152C>G | 5'UTR (SNP) | VAF 20/138 reads (14%) | called by muse, mutect2, varscan2
- CBWD2 | c.154+1072G>C | Intron (SNP) | VAF 38/83 reads (46%) | called by muse, mutect2, varscan2
- ETDB | chrX:135123402 T>C | 5'Flank (SNP) | VAF 27/348 reads (8%) | called by muse, mutect2
- MAP4K1 | c.*12C>T | 3'UTR (SNP) | VAF 20/175 reads (11%) | catalogued as rs756086513; called by muse, mutect2, varscan2
- PDE9A | c.*41C>T | 3'UTR (SNP) | VAF 6/25 reads (24%) | catalogued as rs948905025, COSV99371840; called by muse, mutect2, varscan2
- SMG7 | c.2742+857del | Intron (DEL) | VAF 42/163 reads (26%) | called by mutect2, pindel, varscan2
- SRL | c.62-3445C>T | Intron (SNP) | VAF 39/75 reads (52%) | called by muse, mutect2, varscan2
- TIMP1 | c.453+165T>C | Intron (SNP) | VAF 24/228 reads (11%) | called by muse, mutect2, varscan2
